Gene-level copy-number profile of tumor specimen TCGA-38-4625-01A from TCGA case TCGA-38-4625, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.4 years (24,241 days).
Specimen TCGA-38-4625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d0597d14-df0c-413b-888f-53597d1fb61a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-38-4625-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1a5b3a3d-9f8a-44f3-99e7-c88d0b964f0f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,418; copy number 2: 18,701; copy number 3: 22,314; copy number 4: 9,152; copy number 5: 2,738; copy number 6: 880; copy number 7: 421; copy number 8: 1; copy number 9: 72; copy number 11: 14; copy number 12: 98.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-38-4625-01A-01D-1204-01): tumor purity 0.35, ploidy 2.98, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:216,995,906–217,064,818, 2 genes: AC007749.1, AC007749.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 606 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:113,211,421–125,823,315, 141 genes, copy number 9–12 (within-gene range 5–12) (broad region; genes not listed).
- chr3:30,606,601–30,694,142, 2 genes, copy number 7 (within-gene range 3–7): TGFBR2, AC096921.1.
- chr3:69,048,958–69,123,032, 4 genes, copy number 7: MIR3136, UBA3, ARL6IP5, LMOD3.
- chr3:96,810,838–96,814,407, 1 gene, copy number 8 (within-gene range 4–8): AC109782.1.
- chr6:29,555,629–29,633,976, 1 gene, copy number 7 (within-gene range 5–7): GABBR1.
- chr6:29,585,121–31,463,705, 152 genes, copy number 7 (broad region; genes not listed).
- chr6:117,262,243–117,573,571, 8 genes, copy number 7 (within-gene range 4–7): Z98880.1, VGLL2, ROS1, RN7SKP18, RN7SKP51, AL132671.2, RAP1BP3, AL132671.1.
- chr6:117,457,734–117,457,838, 1 gene, copy number 7: RNU6-253P.
- chr8:37,597,480–43,494,762, 157 genes, copy number 7 (broad region; genes not listed).
- chr8:46,028,804–47,979,521, 42 genes, copy number 7: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P.
- chr8:129,832,301–130,443,674, 14 genes, copy number 11 (within-gene range 6–11): AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1.
- chr8:132,685,007–133,963,259, 29 genes, copy number 9: TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2.
- chr8:140,505,813–141,392,574, 23 genes, copy number 7: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2.
- chr12:104,591,633–104,591,716, 1 gene, copy number 7: MIR3922.
- chr16:50,313,487–51,151,367, 27 genes, copy number 7 (within-gene range 4–7): BRD7, AC007493.2, LINC02178, AC007493.1, NKD1, AC007608.2, AC007608.4, AC007608.1, AC007608.3, SNX20, NOD2, AC007728.3, AC007728.2, CYLD, MIR3181, AC007728.1, LINC02168, LINC02128, AC025810.1, RNA5SP426, LINC02127, AC027688.1, AC027688.2, AC009166.3, SOD1P2, SALL1, AC009166.1.
- chr16:51,176,066–51,178,898, 1 gene, copy number 7: AC009166.2.
- chr18:77,108,284–77,115,726, 2 genes, copy number 7: AC018529.3, AC018529.2.

Autosomal genes at a single copy (total copy number 1): 4,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
